Somatic mutation profile of tumor specimen TCGA-4K-AAAL-01A (aliquot TCGA-4K-AAAL-01A-11D-A435-10) from TCGA case TCGA-4K-AAAL, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 31.8 years (11,622 days).
Specimen TCGA-4K-AAAL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b373eec9-4a58-46fb-acc5-1c836b38e775.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4K-AAAL-10A (Blood Derived Normal), aliquot TCGA-4K-AAAL-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8deaab34-7bb2-44c1-a595-2358eaddf4e0

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, RNA 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ST3GAL2 | c.966G>C p.K322N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | PolyPhen possibly damaging (0.902); catalogued as COSV61596745; called by muse, mutect2, varscan2
- ANKRD50 | c.3834G>C p.K1278N | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- C16orf70 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDYL2 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2
- GK2 | c.387A>T p.K129N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- LCN1 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TEPP | c.337A>C p.K113Q | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.164); called by muse, mutect2
- ADAMTS19 | c.2043A>G p.K681= | Silent (SNP) | VAF 19/139 reads (14%) | called by muse, mutect2, varscan2
- CFAP44 | c.1773C>T p.A591= | Silent (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- MAG | c.540G>T p.L180= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2
- ZNF343 | c.1524C>T p.L508= | Silent (SNP) | VAF 21/121 reads (17%) | called by muse, mutect2, varscan2
- BUD23 | c.702-95C>T | Intron (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- TBC1D29P | n.2536T>C | RNA (SNP) | VAF 43/185 reads (23%) | called by muse, mutect2, varscan2
- VN1R10P | n.472G>A | RNA (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2, varscan2
- VPS35 | c.-10G>T | 5'UTR (SNP) | VAF 11/64 reads (17%) | catalogued as rs763096994; called by muse, mutect2, varscan2
